Somatic mutation profile of tumor specimen TCGA-XE-A8H4-01A (aliquot TCGA-XE-A8H4-01A-31D-A435-10) from TCGA case TCGA-XE-A8H4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 23.9 years (8,728 days).
Specimen TCGA-XE-A8H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5045ee37-cc11-4326-9db7-61c3a9684898.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-A8H4-10A (Blood Derived Normal), aliquot TCGA-XE-A8H4-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eafa0309-aba6-4fe1-b6d5-1806e002ca58

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BANP | c.1210G>C p.E404Q (on ENST00000286122; = p.E376Q on NM_017869.4) | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); catalogued as rs773244452, COSV53735807; called by muse, mutect2
- GNAQ | c.416C>G p.P139R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as CM163867; called by muse, mutect2, varscan2
- PAK3 | c.239T>G p.I80S | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1398096161, COSV53274179; called by muse, mutect2
- SSPN | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.231); catalogued as COSV54381686; called by muse, mutect2
- BZW2 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- COL5A3 | c.2402C>A p.P801H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2
- FANCM | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- LONP1 | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR62 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- FEZF2 | c.1260C>T p.A420= | Silent (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- WNK1 | c.4338A>G p.A1446= (on ENST00000315939 / NM_018979.4; = p.A1199= on NM_014823.3) | Silent (SNP) | VAF 44/179 reads (25%) | catalogued as COSV60026482; called by muse, mutect2, varscan2
- NEB | c.2310+17A>G | Intron (SNP) | VAF 10/115 reads (9%) | catalogued as rs757331071; called by muse, mutect2
